CCDI case PBBWVA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Specialized Gonadal Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/ac7f1612-ee88-41ce-af90-407c42ad7c17

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Sex cord-gonadal stromal tumor, NOS: ICD-O-3 morphology code: 8590/1; Tissue or organ of origin: Ovary; Age at diagnosis: 17.3 years (6,317 days).

Biospecimens (3 samples)
- Sample 0DJBLR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJC34: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJC38: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
